Surgical pathology report (de-identified scan), TCGA case TCGA-23-2078, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2078-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Pathologist:
Assistant:
Attending MD:
Ordering MD:
Copies To:

TCGA-23-2078

DIAGNOSIS:

1. SOFT TISSUE, CUL DE SAC, "TUMOR", EXCISION:
- Positive for serous adenocarcinoma (see comment)
2. SOFT TISSUE, LEFT PELVIC PERITONEUM, BIOPSY:
- Serous adenocarcinoma (see comment)
3. "SIGMOID TUMOR", EXCISION:
- Serous adenocarcinoma (see comment)
- No large intestinal tissue identified
4. LYMPH NODES, RIGHT PELVIC, EXCISION:
- Four lymph nodes negative for metastatic carcinoma (0/4)
5. "RETRO CECAL", EXCISION:
- Positive for serous carcinoma (see comment)
6. LYMPH NODES, RIGHT COMMON [ILIAC], EXCISION:
- Three lymph nodes negative for metastatic carcinoma (0/3)
7. UTERUS, FALLOPIAN TUBES, AND OVARIES, TOTAL ABDOMINAL
HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- High-grade (grade 3) papillary serous carcinoma (see comment) involving:
- Serosal surface and muscular wall of left fallopian tube
- Mucosa and lumen of fimbriated end of left fallopian tube
- Left adnexal soft tissues with extensive involvement of left paratubal soft tissues/mesosalpinx and foci of involvement of left paraovarian soft tissues
- Right adnexal soft tissues, mostly right paratubal soft tissues/mesosalpinx, and focally involving serosal surface of right fallopian tube
- Serosal surface of right ovary
- Bilateral adnexal and regional (paracervical/parauterine) lymphatics and blood vessels
- External surface of posterior cervix
- Serosal surfaces of uterine corpus and lower uterine segment, subserosa of lower uterine segment, and parametrial soft tissues
- Other findings include:
- Small relatively hypocellular uterine leiomyoma with a few smooth muscle cells showing low-grade atypia
- Two benign endometrial polyps
- Inactive (atrophic to weakly proliferative) endometrium with some cystically dilated glands, foci of ciliated metaplasia, and reactive stromal lymphoid aggregates
- Focal adenomyosis

[page 2 of 5]
- Endocervical nabothian cysts
- Cervix with focal epithelial denudation/superficial mucosal erosion, chronic and mild acute inflammation, squamous metaplasia, reactive epithelial changes, and focal atrophic squamous epithelial changes
- Both ovaries with atrophic changes, cystic epithelial inclusions, and serosal adhesions
- Simple benign serous cyst, left ovary
- Left paratubal cystic Walthard rests and endosalpingiosis
- Right paratubal cystic Walthard rests and Wolffian duct remnants
- Adnexal adhesions, bilateral
- Foci of dysplasia, including high-grade dysplasia/serous intraepithelial carcinoma of coelomic epithelium lining adnexal soft tissues/mesosalpinx, bilaterally
8. OMENTUM, OMENTECTOMY:
- "Metastatic" serous adenocarcinoma (see comment)
- Benign angiomatous proliferation
9. SOFT TISSUES, "LEFT GUTTER AND COLON TUMOR", EXCISION:
- Positive for serous adenocarcinoma (see comment)
10. LYMPH NODES, LEFT PELVIC, EXCISION:
- One lymph node negative for metastatic carcinoma (0/1)
- Aggregate of serous carcinoma cells in perinodal fat
11. SOFT TISSUE, IP LIGAMENT, EXCISION:
- Positive for serous adenocarcinoma (see comment)
12. SOFT TISSUE, "RIGHT PERINEPHRIC TUMOR", EXCISION:
- Positive for serous carcinoma (see comment)
13. VERMIFORM APPENDIX, APPENDECTOMY:
- "Metastatic" serous carcinoma involving mesoappendix and periappendiceal tissues (see comment)
- Fibrous obliteration of lumen of appendix

COMMENT: The left fallopian tube was not enlarged. Most of the grossly evident tumor in the left adnexa appeared to be paratubal, rather than intratubal. Although this high-grade papillary serous carcinoma extensively involves the left paratubal soft tissues/ligaments, serosal surface of the left fallopian tube, focally involves the muscular wall of the left fallopian tube and is present within the lumen and focally involves the mucosa of the fimbriated end of the left fallopian tube, a peritoneal primary carcinoma rather than a primary tubal carcinoma is favored. The tumor exhibits features of high-grade serous carcinoma, for the most part, and focally pseudotransitional features. Growth patterns of tumor include papillary, glandular and solid. Tumor-associated psammoma bodies are present in many of the involved sites. Lymphovascular invasion by tumor is present in most of the involved sites. Foci of tumor necrosis are present. Secondary acute and chronic inflammatory changes, reactive stromal changes, fibrosis, adhesions, and secondary reactive mesothelial proliferation are present in most of the involved sites. No metastatic tumor is identified in the sampled lymph nodes. The lymph nodes do show reactive lymphoid proliferation, sinus histiocytosis, foci of fibrosis and/or calcifications.

=====

HISTORY: Pelvic mass

MICROSCOPIC:
See Diagnosis.

GROSS:
1: CUL DE SAC TUMOR

[page 3 of 5]
Labeled "cul de sac tumor" and received in formalin are four pieces of firm fibrotic tan tumor measuring 1.2 x 1 x 0.5 cm to 2.4 x 1.8 x 1.5 cm.

Representative section.

A. 1

2: LEFT PELVIC PERITONEUM

Labeled "left pelvic peritoneum" and received in formalin is a 7.5 x 1.5 x 0.5 cm yellow-tan fibroadipose tissue with multiple firm tan-white nodular aggregates of tumor. The tumor nodules range from about 0.2 to 0.6 cm in maximum dimension.

Representative sections.

B. 3

3: SIGMOID TUMOR

Labeled "sigmoid tumor" and received in formalin is an aggregate of semisoft friable and firm tan-white tumor and scant blood clot.

Representative sections.

C. 4

4: RIGHT PELVIC LYMPH NODE

Labeled "right pelvic lymph node", received in formalin and transferred to Bouin's fixative, are two pieces of yellow lobulated adipose tissue measuring 3.5 x 1.5 x 0.5 cm and 5.5 x 1.5 x 0.5 cm. Dissection of the fat reveals four semisoft tan lymph nodes ranging from about 0.2 to 0.8 cm in maximum dimension. The lymph nodes are each entirely embedded along with some of the perinodal fat.

D. Four lymph nodes and perinodal fat - 4

5: RETRO CECAL

Labeled "retro cecal" and received in formalin is a 7.5 x 2.5 x 0.8 cm aggregate of red-brown muscular tissue, tan fibrous tissue, yellow fat and multiple nodular aggregates of firm tan-white tumor. The tumor nodules measure up to about 0.8 cm in diameter.

Representative sections.

E. 3

6: RIGHT COMMON LYMPH NODE

Labeled "right common lymph node", received in formalin and transferred to Bouin's, are two pieces of yellow lobulated adipose tissue measuring 2.5 x 1.5 x 1 cm and 3.2 x 2 x 0.5 cm. Dissection of the fat reveal three semisoft tan lymph nodes, 0.2, 0.6, and 0.8 cm in maximum dimensions. The lymph nodes are each entirely embedded along with some of the perinodal fat.

F. Three lymph nodes - 2

7: UTERUS AND TUBES

Labeled "uterus and tubes", received fresh in the Operating Room and subsequently fixed in formalin, is a uterus with bilateral ovaries and fallopian tubes. The specimen weighs 90 grams. The uterine corpus is symmetric, measuring 8 cm superior to inferior, 5 cm cornu to cornu, and 3 cm anterior to posterior. The serosa is pink-tan with adhesions and a few tiny to small granular to nodular deposits of firm tan tumor. The cervix has a length of 3 cm and a diameter of 2.5 cm. There is a 0.4 cm slit-shaped patent os. The ectocervical mucosa is tan and smooth. The transformation zone is distinct. The endocervical canal is about 2 cm long and lined by tan rugose mucosa. Cut sections of the cervix reveal several mucus-filled cysts, up to 0.2 cm in diameter. The endometrial cavity is 4.5 cm in length and 2.5 cm in width and is mostly lined by soft red-tan endometrium with an average thickness of 0.1 cm. Two semisoft tan endometrial polyps are present. One is located in the fundus and measures about 1 cm in maximum dimension and the other is present in the posterior uterine corpus and measures about 0.8 cm in maximum dimension.

[page 4 of 5]
diameter. The muscular uterine wall has a maximum thickness of about 1.5 cm. There is a 1 x 0.9 x 0.9 cm well-circumscribed subserosal leiomyoma with a firm white focally whorled cut surface without hemorrhage or necrosis in the posterior corpus. The right ovary is 2.2 x 1.1 x 0.4 cm and has a firm tan-yellow cerebriform external surface with a few adhesions and a 0.2 cm diameter red-tan granular surface lesion. Cut surfaces of the right ovary reveal a narrow rim of yellow-tan cortical stroma, a few firm white corpora albicantia, a few minute cystic spaces, and no grossly evident invasive tumor. The right tube is 5.5 cm in length and 0.5 cm in diameter. The fimbriated area is identified. There are multiple small white firm nodules ranging from 0.1 to 0.3 cm on the serosal surface of the right fallopian tube and involving the paratubal soft tissues. A few tiny right paratubal cysts are also noted. The lumen of the right fallopian tube is patent and the wall is grossly unremarkable. The left ovary is 2.2 x 1.1 x 0.4 cm and has a firm yellow-tan cerebriform external surface with a 0.2 cm firm nodular surface lesion suspicious for tumor. Cut surfaces of the left ovary are remarkable for a narrow rim of yellow-tan cortical stroma, several firm white corpora albicantia and a 0.8 cm thin-walled, clear fluid-filled cyst lined by smooth tan tissue. There is no gross evidence of invasive tumor in the left ovary. The left tube is 5.5 cm in length and 0.5 cm in diameter. The fimbriated area is identified. There are a 3.5 x 2.2 x 2 cm white-tan mass and 1 x 0.7 x 0.7 cm white-tan firm mass in the paratubal tissues. There are also multiple tiny to small firm nodular aggregates of apparent tumor ranging from about 0.1 to 0.8 cm involving the serosal surface of the left fallopian tube and fimbriated end of the tube. The lumen of the left fallopian tube is patent, for the most part, but partially occupied by tumor at the fimbriated end.

Representative sections.

- G. Left adnexal tumor mass, large nodule - 1
- H. Smaller nodule, left adnexal tumor - 1
- I. Left tube with tumor - 1
- J. Left ovary and paratubal tissues - 2
- K. Right ovary - 1
- L. Right tube - 1
- M. Right tube - 1
- N. Anterior cervix - 1
- O. Posterior cervix - 1
- P. Anterior lower uterine segment - 1
- Q. Fundic polypoid lesion - 1
- R. Anterior corpus - 1
- S. Posterior corpus with polyp - 1
- T. Leiomyoma - 1

8: OMENTUM

Labeled "omentum" and received in formalin is a 35 x 5.5 x 3.5 cm yellow lobulated adipose tissue. There is a 3 x 2 x 1.5 cm white-tan firm tumor nodule and multiple smaller tan-white firm nodules ranging from 0.1 to 0.7 cm.

Representative sections.

- U. 1
- V. 2

9: LEFT GUTTER AND COLON TUMOR

Labeled "left gutter and colon tumor" and received in formalin is a 6 x 3 x 0.5 cm portion of yellow lobulated adipose tissue with multiple small firm white-tan irregular to nodular tumor aggregates ranging from 0.1 to 0.5 cm in greatest dimension. Also received is a irregular firm white-tan tumor mass measuring 2 x 2 x 1.5 cm.

Representative sections.

- W. 2

10: LEFT PELVIC LYMPH NODES

[page 5 of 5]
Labeled "left pelvic lymph nodes", received in formalin and [REDACTED] is a 3 x 2 x 0.5 cm yellow lobulated adipose tissue and a single 0.2 cm soft tan lymph node. Entirely submitted.

X. Multiple

11: IP LIGAMENT

Labeled "IP ligament" and received in formalin is a 2.2 x 1.2 x 0.5 cm yellow adipose tissue with pink-tan firm tissue. Also received is a 0.6 x 0.3 x 0.2 cm white-tan firm piece of tumor. Representative sections.

Y. 4

12: RIGHT PERINEPHRIC TUMOR

Labeled "right perinephric tumor" and received in formalin is a 1.8 x 0.4 x 0.2 cm pink-tan fibrous membranous tissue. Also received is a 1.2 x 1 x 0.5 cm ovoid firm white-tan tumor mass. The latter is bisected prior to embedding. Entirely submitted.

Z. 3

13: APPENDIX

Labeled "appendix" and received in formalin is a 5 cm long vermiform appendix, measuring 0.2 cm in diameter, with attached fatty meso-appendix that measures 2.1 cm in width and up to 1 cm in thickness. Within the mesoappendix and focally involving the external aspect of the appendix, there are tiny to small nodular aggregates of firm tan tumor, up to 0.2 cm in diameter. The lumen of the appendix is partially obliterated by fibrous tissue. Representative sections.

AA. Appendix and mesoappendix - 2

OPERATIVE CONSULT (GROSS):

7. Uterus and tubes:

- Uterine cavity shows a polyp; no gross evidence of tumor
- Tumor on fallopian tube surface and in omentum
- Tumor taken for clonogenic assay and for research

Special Studies:

See Also: None

Source: NCI Genomic Data Commons file aa103e10-fd44-429b-bfbc-a2aa059007bb (TCGA-23-2078.19ED5FBE-17E1-43F3-BFA0-32F474A00BE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).